Somatic mutation profile of tumor specimen 0DPAOJ from CCDI case PBCDEH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Myxopapillary ependymoma; Tissue or organ of origin: Spinal cord; Age at diagnosis: 6.2 years (2,267 days).
Specimen 0DPAOJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8421fa01-56b3-4818-852d-1c5db4d48751.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPAO9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6fed6b75-8307-4f0f-8102-2b10c09fbf98

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.4957C>T p.R1653C (on ENST00000358273 / NM_001042492.3; = p.R1632C on NM_000267.3) | Missense Mutation (SNP) | VAF 58/800 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs876659922; ClinVar: uncertain significance; called by muse, mutect2
- PLPPR4 | c.1887C>A p.N629K | Missense Mutation (SNP) | VAF 32/746 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); called by muse, mutect2
- SAMD15 | c.1909A>G p.I637V | Missense Mutation (SNP) | VAF 30/494 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- NLRC3 | c.2613C>T p.A871= | Silent (SNP) | VAF 23/530 reads (4%) | called by muse, mutect2
- TMEM132D | c.1953C>T p.L651= | Silent (SNP) | VAF 188/819 reads (23%) | catalogued as rs374463645; called by muse, mutect2, varscan2
- TMEM131 | c.4724-26C>T | Intron (SNP) | VAF 39/329 reads (12%) | catalogued as rs752567547, COSV51777555; called by muse, mutect2, varscan2
- ZNF213 | c.*83T>C | 3'UTR (SNP) | VAF 9/124 reads (7%) | called by muse, mutect2
